Somatic mutation profile of tumor specimen TCGA-S7-A7WP-01A (aliquot TCGA-S7-A7WP-01A-11D-A35I-08) from TCGA case TCGA-S7-A7WP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 25.3 years (9,241 days).
Specimen TCGA-S7-A7WP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd38936c-2570-44ee-b3b0-61b01db0635a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WP-10A (Blood Derived Normal), aliquot TCGA-S7-A7WP-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/525d2d9a-89cf-4c96-a704-c5f4fd2bc7be

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TCTE1 | c.1018A>C p.N340H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZFC3H1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.019); called by muse, mutect2, varscan2
